Somatic mutation profile of tumor specimen TCGA-ED-A7XP-01A (aliquot TCGA-ED-A7XP-01A-11D-A34Z-10) from TCGA case TCGA-ED-A7XP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.4 years (19,504 days).
Specimen TCGA-ED-A7XP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 558e6f99-5ce2-4cb3-8b50-515b09810141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A7XP-10A (Blood Derived Normal), aliquot TCGA-ED-A7XP-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e401e733-32b8-4207-bba0-b2f21e5b6b42

The open-access MAF lists 72 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 15/135 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3419G>A p.G1140D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs779039245, COSV65891494; called by muse, mutect2, varscan2
- AMH | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV55553938, COSV55554399; called by muse, mutect2
- APOB | c.6035G>A p.R2012Q | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as rs749146264, COSV51931949; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP31 | c.2402A>C p.K801T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV51791787; called by muse, mutect2, varscan2
- AURKA | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV57168220; called by muse, mutect2, varscan2
- C11orf54 | c.775-1G>A p.X259_splice (on ENST00000331239; = p.X209_splice on NM_014039.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/127 reads (27%) | catalogued as rs1196671772, COSV58680072; called by muse, mutect2, varscan2
- C16orf70 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as rs528433156, COSV54626858; called by muse, mutect2, varscan2
- C9orf135 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs372154813; called by muse, mutect2, varscan2
- CACNA1E | c.2553C>A p.S851R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62390453; called by muse, mutect2, varscan2
- CASP4 | c.925+1G>T p.X309_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV67744355; called by muse, mutect2, varscan2
- CFL1 | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV57379440; called by muse, mutect2, varscan2
- CHD7 | c.1878C>A p.N626K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV71109264; called by muse, mutect2, varscan2
- COL4A2 | c.3226G>C p.G1076R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64627272; called by muse, mutect2, varscan2
- CPS1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs148654695, COSV51804455; called by muse, mutect2, varscan2
- DDO | c.969G>T p.R323S (on ENST00000368924 / NM_001368172.1; = p.R264S on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1236110498, COSV64470001; called by muse, mutect2, varscan2
- DMD | c.8893G>T p.D2965Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58905124, COSV58908980; called by muse, mutect2, varscan2
- DNAH7 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV56760292; called by muse, mutect2, varscan2
- ENTPD1 | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64601222; called by muse, varscan2
- FFAR4 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs567274570, COSV65178446, COSV65178781; called by muse, mutect2, varscan2
- FGF14 | c.455A>C p.N152T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65941151; called by mutect2, varscan2
- GPATCH8 | c.2390G>T p.R797L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV59194287; called by muse, mutect2, varscan2
- GPHN | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV59478157; called by muse, mutect2, varscan2
- IFNA13 | c.73T>G p.C25G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71924477; called by muse, mutect2, varscan2
- INHA | c.827G>T p.W276L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54717302, COSV54720037; called by muse, mutect2, varscan2
- JAK1 | c.2613A>C p.E871D | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); catalogued as COSV61090130; called by muse, mutect2, varscan2
- KCNH1 | c.2927C>A p.P976Q (on ENST00000271751 / NM_172362.3; = p.P949Q on NM_002238.4) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV55077701; called by muse, mutect2, varscan2
- KDM5A | c.1476C>G p.I492M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66991829, COSV66996239; called by muse, mutect2, varscan2
- MAP2 | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52288021; called by muse, mutect2, varscan2
- PGP | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV57027599; called by muse, varscan2
- PIK3CG | c.3196A>T p.K1066* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV63247542; called by muse, mutect2, varscan2
- PSMB10 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52123046; called by muse, mutect2, varscan2
- PTPN13 | c.3560C>A p.S1187Y (on ENST00000411767 / NM_080683.3; = p.S1168Y on NM_006264.3) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV57405937; called by muse, mutect2, varscan2
- RASGRP2 | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100818292; called by muse, mutect2
- SEC24B | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | catalogued as COSV54497993; called by muse, mutect2, varscan2
- SEPTIN4 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.442); catalogued as COSV58727633; called by muse, mutect2, varscan2
- SGK2 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58312896, COSV58313460, COSV58314511; called by muse, mutect2, varscan2
- SLC26A11 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV58339049; called by muse, mutect2, varscan2
- SLC7A7 | c.1451A>C p.Q484P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53536864; called by muse, mutect2, varscan2
- SLC9C1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747653983, COSV59887489; called by muse, mutect2, varscan2
- SPAG1 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52559288; called by muse, mutect2, varscan2
- ST7L | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58308322; called by muse, mutect2
- UGT2B28 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs756354201, COSV59431471; called by muse, mutect2, varscan2
- USP48 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57609072; called by muse, mutect2, varscan2
- WDR27 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370579184; called by muse, mutect2, varscan2
- ZNF195 | c.1809G>T p.E603D (on ENST00000399602 / NM_001130520.3; = p.E531D on NM_007152.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV50002969; called by muse, mutect2, varscan2
- ZNF329 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV63772195; called by muse, mutect2, varscan2
- COL9A1 | c.601del p.I201Lfs*6 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | called by mutect2, pindel, varscan2
- DST | c.499_511del p.G167Ffs*27 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- MYF5 | c.733del p.A245Lfs*19 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- SEC22A | c.701del p.G234Efs*25 | Frame Shift Del (DEL) | VAF 96/328 reads (29%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.1207_1220del p.I403Sfs*2 | Frame Shift Del (DEL) | VAF 78/100 reads (78%) | called by mutect2, pindel, varscan2
- TMEM44 | c.974del p.G325Dfs*16 (on ENST00000392432 / NM_001166305.2; = p.G278Dfs*16 on NM_138399.5) | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- AMER1 | c.973T>C p.L325= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV57659244, COSV57663087; called by muse, mutect2
- ARCN1 | c.252G>A p.R84= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV50614721; called by muse, mutect2, varscan2
- CCN6 | c.15C>A p.L5= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs781883423, COSV100036945, COSV57889173; called by muse, mutect2, varscan2
- CUL3 | c.711A>G p.V237= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as rs1426166050, COSV52363782; called by muse, mutect2, varscan2
- FLRT2 | c.1896G>A p.G632= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV58139888; called by muse, mutect2, varscan2
- HMCN1 | c.4488G>A p.L1496= | Silent (SNP) | VAF 127/154 reads (82%) | catalogued as COSV54893353; called by muse, mutect2, varscan2
- IFI30 | c.6C>T p.T2= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55847396, COSV55847649; called by muse, mutect2
- INSIG1 | c.585C>T p.A195= | Silent (SNP) | VAF 62/203 reads (31%) | catalogued as COSV60920227; called by muse, mutect2, varscan2
- IRX1 | c.588C>A p.R196= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV57358184, COSV57358980; called by muse, mutect2, varscan2
- KIAA1586 | c.1074A>C p.I358= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV66056441; called by muse, varscan2
- LARP4 | c.2130A>G p.R710= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53321880; called by muse, mutect2, varscan2
- NDUFS5 | c.189C>T p.F63= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs372457176, COSV65892252; called by muse, mutect2, varscan2
- PARP1 | c.195G>A p.R65= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV64687109; called by muse, mutect2, varscan2
- PRRG1 | c.33C>A p.A11= | Silent (SNP) | VAF 117/326 reads (36%) | catalogued as COSV66157318; called by muse, varscan2
- ST6GAL2 | c.189C>A p.G63= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV64527677, COSV64527700; called by muse, mutect2, varscan2
- TPO | c.465A>T p.T155= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV61099818; called by muse, mutect2, varscan2
- RALGAPA1 | c.*114G>A | 3'UTR (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51880932; called by muse, mutect2, varscan2
